Surgical pathology report (de-identified scan), TCGA case TCGA-CD-A48C, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site ILSBio, specimen TCGA-CD-A48C-01A (Primary Tumor).

[page 1 of 5]
Clinical Case Report

(For Collection of Specimens for Research)

ICD-0-3
adenocarcinoma, NOS
8140/3
Site: Stomach, antrum C16.3
In 9/26/12

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator _____

Signature _____

Date _____

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
	1 m 56	☐ Single ☒ Married	WHITE	
Gender	Weight	☐ Divorced ☐ Widow	Blood Pressure	Heart Rate
☐ Male ☒ Female	53 kg		117	

HISTORY OF PRESENT ILLNESS
Chief Complaints: Abdominal pain, black & tarry stool
Symptoms: weight loss
Clinical Findings:
Performance Scale (Karnofsky Score):
☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day ☒ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY			
Menopausal Status ☐ Pre-menopausal ☐ Peri-Menopausal ☒ Post-menopausal	Date of First Menses		# of Pregnancies
	Date of Last Menses		# of Live Births
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other:			☐ Hormone Replacement Therapy:

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive: _____		EA	☐ Negative ☐ Positive: _____		
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____		
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____		
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____		
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____		
B/T Cell Markers:						

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy	A tumour was found in the pylorus.	
MRI		
Biopsy		

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Location of Suspected Involved Lymph Nodes		Location of Suspected Distant Metastasis
Clinical Staging		Date of Diagnosis
T3 N1 M0 Stage: IIIA		

Treatment Information

SURGICAL TREATMENT			
Procedure			Date of Procedure
Extended Gastrectomy			
Primary Tumor			
Organ	Detailed Location	Size	
Stomach Tumor	Anterior	8 x 6 x 2 cm	
Extension of Tumor			
Lymph Nodes			
Description	Location of Lymph Nodes	# of Lymph Nodes	
Palpable, Non-Dissected Lymph Nodes			
Dissected Lymph Nodes			
Distant Metastasis			
Organ	Detailed Location	Size	
Surgical Staging			
T3 N1 M0 Stage: IIIA			

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

Collected by: ____

____ Date:

Time: ____

Preserved by: ____

____ Date:

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
min		min		min			

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Stomach Tumor	8 x 6 x 2 cm	Anterior	6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 3 N1 M 0		Stage: IIIA	
Notes: nodes (M1, M2)			

[page 5 of 5]
CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION			STRUCTURAL PATTERN		
	+	-		+	-
Diffuse		X	Streaming		
Mosaic	X		Storiform		
Necrosis		X	Fibrosis		
Lymphocytic Infiltration	X		Palisading		
Vascular Invasion		X	Cystic Degeneration		
Clusterized	X		Bleeding		
Alveolar Formation		X	Myxoid Change		
Indian File		X	Psamomma/Calcification		

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell	X		Round Cell			Large Cell		
Spindle Cell			Cell Stratification	X		Fibroblast			Small Cell		
Keratin			Secretion	X		Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole	X		Lipoblast			Inflam. Cell		
Pearl			Gland formation	X		Myoblast			Plasma Cell		
Otherwise Specified: D, 58% D, 68% D, 350% D, 420%											

2. Cellular Differentiation:

Well	Moderately	Poor
		X

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis				X
Hyperchromatism				
Nucleolar Prominent			X	
Multinucleated Giant Cell			X	
Mitotic Activity				X
Nuclear Grade				X

Histological Diagnosis: Adenocarcinoma, NOS, G 3

Comments: M, M2: Carcinoma metastasized to LN

Director

Date

*(INTEGRATED REPORT OF FINDINGS BY CONTRIBUTOR AND

PATHOLOGIST STAFF FOR RESEARCH (USE ONLY)

Source: NCI Genomic Data Commons file 199586a2-c856-4575-b151-4ae3ab04ae03 (TCGA-CD-A48C.55E19EDE-AA9B-42EE-957B-20A9B9CFA321.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).